Somatic mutation profile of tumor specimen MP2PRT-PAULBG-TMP1-A (aliquot MP2PRT-PAULBG-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAULBG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,193 days).
Specimen MP2PRT-PAULBG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff09bb5-6d48-42a8-adeb-a6307f7e7317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULBG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULBG-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e619ced4-44c5-4947-acdc-1912f8bc4efd

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP9B | c.2215G>A p.G739S | Missense Mutation (SNP) | VAF 64/561 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373430011; called by muse, mutect2, varscan2
- IGHV1-46 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1337425972; called by muse, varscan2
- OLFM3 | c.253C>A p.Q85K (on ENST00000338858 / NM_001288821.1; = p.Q65K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV58802385; called by muse, mutect2, varscan2
- PHF24 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 156/381 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs199743237; called by muse, mutect2, varscan2
- PRAM1 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 52/544 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1329255775, COSV55313842; called by muse, mutect2
- CPA3 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- IGHV1-46 | c.348_349insGTGGGTGGGATGAGGGGGGGG p.A116_R117insVGGMRGG | In Frame Ins (INS) | VAF 11/38 reads (29%) | called by mutect2, pindel
- USP15 | c.2127dup p.R710Tfs*14 (on ENST00000280377 / NM_001351159.2; = p.R681Tfs*14 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 42/321 reads (13%) | called by mutect2, pindel, varscan2
- DNAH9 | c.11976A>G p.A3992= | Silent (SNP) | VAF 166/407 reads (41%) | called by muse, mutect2, varscan2
- SPRR5 | c.138G>A p.P46= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1445525986; called by muse, mutect2, varscan2
- ZNF451 | c.1752C>T p.N584= | Silent (SNP) | VAF 15/450 reads (3%) | called by muse, mutect2
